Surgical pathology report (de-identified scan), TCGA case TCGA-EA-A97N, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Asterand, specimen TCGA-EA-A97N-01A (Primary Tumor).

[page 1 of 2]
TSS Patient ID:

Surgical Date:

Gross Description: Uterus with colli uteri is 9x6 cm in its size. In colli uteri is dense gray-rose tumor 8x4 cm in its size with invasion to serosa. Endometrial hyperplasia.

Microscopic Description: 1) Colli uteri -- squamous cell carcinoma, G2.

2) Glandular hyperplasia of the endometrium.

3) Vaginal cuff -- leukoplakia of stratified squamous epithelium.

4) Right and left parametrium -- fatty and fibrosis tissues without pathological changes.

5) Right lymph nodes - 3 examined lymph nodes demonstrate lipomatosis, sinus histiocytosis.

6) Left lymph nodes -- 3 examined lymph nodes demonstrate lipomatosis, sinus histiocytosis.

7) Presacralis lymph nodes -- 4 examined lymph nodes demonstrate lipomatosis, sinus histiocytosis.

Diagnosis Details: Tumor Features: Unknown, Tumor Extent: Lesion greater than 4.0cm, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments: 8.5. Original CRF reads T1. But tumor size more 4 cm - stage T2a2 according to the AJCC 7th edition of TNM-classification.

Formatted Path Reports: CERVIX TISSUE CHECKLIST

Specimen type: Radical hysterectomy

Tumor site: Cervix

Tumor size: 4 x 0 x 8 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Not specified

Lymph nodes: 0/10 positive for metastasis (Suprailiac right, left; presacralis 0/10)

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: No

ICD O-3
Carcinoma, squamous cell NOS
807013
Site Cervix NOS
C53.9
4/7/14

[page 2 of 2]
Additional pathologic findings: Not specified

Comments: None

Source: NCI Genomic Data Commons file 07fe2147-17dd-497b-9cf4-d9f46c07e6a0 (TCGA-EA-A97N.23982BB4-8B3A-4F8B-98EE-11E63B92FA17.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).